BEATAML1.0 case 2096 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/98c21e0b-1373-4785-8edf-345c55fd370c

Biospecimens (16 samples)
- Samples BA2326R, BA2341R, BA2390R, BA2392R, BA2430R, BA2448R, BA2506R, BA2611R, BA2612R, BA2730R, BA2845R, BA2973R, BA3105R, BA3218R, BA3276R, BA3402R (16 with the same recorded description): Sample type: Control Analyte; Tissue type: Normal; Preservation method: Fresh.
